Somatic mutation profile of tumor specimen TARGET-10-PAKSWW-03A (aliquot TARGET-10-PAKSWW-03A-01D) from TARGET case TARGET-10-PAKSWW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.1 years (5,516 days).
Specimen TARGET-10-PAKSWW-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1a4a876-f78e-4d98-be34-8db53520a43e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAKSWW-10A (Blood Derived Normal), aliquot TARGET-10-PAKSWW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c4d24b8-ab44-480e-a4d1-7b794430e5a6

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 15, Silent 6, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK1 | c.1972G>T p.V658F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519753, COSV61086927, COSV61091213; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 29/132 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 27/82 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AEBP1 | c.3187A>G p.T1063A | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as COSV56258757; called by muse, mutect2, varscan2
- DNAH7 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.714); catalogued as rs769106832, COSV56764893; called by muse, mutect2, varscan2
- DNAH9 | c.2711A>T p.K904M | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as COSV52355253; called by muse, mutect2, varscan2
- DOT1L | c.140A>T p.E47V | Missense Mutation (SNP) | VAF 261/272 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67108264; called by muse, mutect2, varscan2
- EMP2 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs749960492, COSV63996073; called by muse, mutect2, varscan2
- GRID1 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.058); catalogued as rs777631027; called by muse, mutect2, varscan2
- SMC1A | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59131159; called by muse, mutect2, varscan2
- TFEC | c.515+1G>A p.X172_splice | Splice Site (SNP) | VAF 24/66 reads (36%) | catalogued as rs1377961775, COSV55398914; called by muse, mutect2, varscan2
- TIPRL | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63207902; called by muse, mutect2, varscan2
- MGAM | c.2129G>T p.R710M | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR6B1 | c.619T>G p.F207V | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLITRK6 | c.1131T>A p.S377R | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SULT2B1 | c.662T>A p.V221E (on ENST00000201586 / NM_177973.2; = p.V206E on NM_004605.2) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- ARHGAP42 | c.2097A>C p.S699= | Silent (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2
- CADPS2 | c.1134G>A p.K378= | Silent (SNP) | VAF 56/103 reads (54%) | called by muse, mutect2, varscan2
- FTCD | c.117C>T p.D39= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs751420192; called by muse, mutect2, varscan2
- SLC23A1 | c.1401C>T p.F467= | Silent (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- STXBP5 | c.537C>T p.Y179= | Silent (SNP) | VAF 65/146 reads (45%) | catalogued as rs750040194; called by muse, mutect2, varscan2
- TRHDE | c.630C>T p.L210= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
